Surgical pathology report (de-identified scan), TCGA case TCGA-L5-A4ON, project TCGA-ESCA (Esophageal Carcinoma), tissue source site University of Michigan, specimen TCGA-L5-A4ON-01A (Primary Tumor).

[page 1 of 3]
1CD-0-3
adenocarcinoma, NOS 8140/3
Site: esophageal, distal third C15.5

lw
10/9/12

PROCEDURE: SPHS

Source of Specimen: Omental nodule. Esophageal cancer.

PROCEDURE: SPGD

1. "Omentum, nodule" A tan aggregate of fat.
Frozen section control.

2. "Proximal stomach - distal esophagus" Received in formalin in a medium

[page 2 of 3]
PREVIOUS DIAGNOSIS INQUIRY

PAGE #: 3
SEX: M

container is a portion of distal esophagus and proximal stomach. The distal esophagus measures 7.5 cm in length and the proximal stomach measures 4.5 cm in length. There is a 5.0 x 3.5 x 2.0 cm portion of fibroadipose tissue with multiple potential lymph nodes. Soft tissue margin inked black. The distal esophagus contains a fungating 4.0 x 2.2 cm mass that rises 1.2 cm above the surrounding gray-tan, wrinkled mucosa. This mass is located 2.8 cm from the proximal esophagus margin and 4.0 cm from the distal stomach margin. The soft tissue underlying the tumor is inked black. Upon sectioning, the mass appears to be limited to the mucosa with no obvious areas of extension into the underlying wall identified grossly.

2A. Proximal esophageal margin. (

2B. Distal gastric margin.

2C-F. Complete cross sections of tumor with underlying esophageal wall. each)

2G. Three potential lymph nodes.

2H-J. Remainder of fibroadipose tissue.

3. "Mediastinal lymph node" Received in formalin in a small container is a 3.0 x 1.8 x 1.1 cm portion of adipose tissue. Four possible lymph nodes are identified up to 1.0 cm in greatest dimension. Submitted whole. One cassette. fat retained)

4. "Proximal esophageal margin" Received in formalin in a small container is a 1.3 cm in length x 2.2 cm in diameter unoriented segment of esophagus. The specimen contains one stapled end and one opened end. Both the adventitial and mucosal surfaces are unremarkable. Submitted whole, opened end en face. One cassette. (, staple line retained)

5. "Para-esophageal lymph node" Received in formalin in a small container is a 2.2 x 1.8 x 0.9 cm aggregate of adipose tissue. One possible lymph node is identified measuring 1.0 cm in greatest dimension. Bisected. One cassette fat retained)

FROZEN SECTION REPORT

Fibroadipose tissue, negative for neoplasm.

have reviewed and interpreted the frozen section material at the time it was requested.

Permanent sections confirm frozen section report.

PROCEDURE: SPMI

ESOPHAGUS CARCINOMA

[page 3 of 3]
PREVIOUS DIAGNOSIS INQUIRY

PAGE #: 4
SEX: M

LOCATION: Lower esophagus

SIZE: Microscopic

Has it been treated preoperatively with chemo/radiation therapy: No

TYPE OF CARCINOMA: Adenocarcinoma arising in Barrett's mucosa

DEPTH OF INVASION: Submucosa

NUMBER OF POSITIVE LYMPH NODES / TOTAL NUMBER OF NODES EXAMINED: 1/10

DISTANT METASTASIS: Unknown

RESECTION MARGIN INVOLVED: No

T1b N1

PROCEDURE: SPOX

2&4. Distal esophagus, resection: Microscopic invasive adenocarcinoma arising in polypoid high grade dysplasia in a background of Barrett's mucosa with flat high grade dysplasia, invading barely into superficial submucosa. Margins negative. Five lymph nodes negative for neoplasm. Please see template for details.

1. Omentum, biopsy: Negative for neoplasm.

3. Mediastinal lymph node, excision: Four lymph nodes negative for neoplasm.

5. Para-esophageal lymph node, excision: Metastatic adenocarcinoma in one lymph node.

I, [redacted] the signing staff pathologist, have personally examined and interpreted the slides from this case.

HI/PA Discrepancy		

Source: NCI Genomic Data Commons file 0dc32ed0-4293-4aa1-89a6-eac426bdd9eb (TCGA-L5-A4ON.3368C9BD-3CDD-4382-82DF-E555A39DF30A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).